Somatic mutation profile of tumor specimen RC-B65G-TBP1-A (aliquot RC-B65G-TBP1-A-1-0-D-A93N-47) from RC case RC-B65G, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants); Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 38.7 years (14,143 days).
Specimen RC-B65G-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7240eb11-37f7-4c77-9bac-53b6ed9dcfaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B65G-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B65G-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4fc0e9d-3b4d-4797-a81a-98326cd0ab72

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRKCB | c.1054A>G p.S352G | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV57781390; called by muse, mutect2
- SLC18A3 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV60324860; called by muse, varscan2
- FYN | c.1565A>T p.D522V | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ROBO3 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCDHGA11 | c.2268C>T p.H756= | Silent (SNP) | VAF 35/253 reads (14%) | catalogued as COSV53908516, COSV99535867; called by muse, mutect2, varscan2
